Somatic mutation profile of tumor specimen ALCH-B24N-TTP1-A (aliquot ALCH-B24N-TTP1-A-1-0-D-A773-36) from ALCHEMIST case ALCH-B24N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.7 years (24,716 days).
Specimen ALCH-B24N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2aa12fb5-bd04-4d3b-8144-3c8d94a02f6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B24N-NB1-A (Blood Derived Normal), aliquot ALCH-B24N-NB1-A-1-0-D-A773-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ce0dfd6-d94a-4cab-a468-94706ea3b712

The open-access MAF lists 218 somatic variants for this specimen: 152 protein-altering or splice-affecting, 44 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 44, Nonsense Mutation 14, Intron 9, 5'UTR 6, Splice Site 4, 3'UTR 3, 5'Flank 2, RNA 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 38/245 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 22/288 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1057519995, COSV52663197, COSV52713501, COSV52816344; ClinVar: likely pathogenic; called by muse, mutect2
- ADAMTS4 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 26/393 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as rs1242506429, COSV100917463; called by muse, mutect2
- ADGRG7 | c.1720G>C p.G574R | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56301051; called by muse, mutect2
- ALDH7A1 | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68629320; called by muse, mutect2
- CACNA1C | c.4726G>A p.G1576R | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs1355868960; called by muse, mutect2
- COL6A3 | c.2801G>A p.S934N | Missense Mutation (SNP) | VAF 21/297 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99796250; called by muse, mutect2
- CRYGN | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs946749200; called by muse, mutect2, varscan2
- CSF2RB | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs770407372, COSV53256425; called by muse, mutect2
- DICER1 | c.5380G>T p.E1794* | Nonsense Mutation (SNP) | VAF 26/415 reads (6%) | catalogued as COSV58617598; called by muse, mutect2
- DICER1 | c.5379G>T p.E1793D | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.761); catalogued as COSV58621905; called by muse, mutect2
- DLG2 | c.2255A>G p.D752G | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs1283976760, COSV54650860; called by muse, mutect2
- DLL1 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 30/684 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs778363506, COSV64537833; called by muse, mutect2
- DNAH1 | c.1451T>C p.V484A | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs1450652487; called by muse, mutect2
- FREM1 | c.2305A>G p.T769A | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1437727369; called by muse, mutect2
- GLUD2 | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100047086, COSV60151937; called by muse, mutect2
- GPR101 | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.44); catalogued as rs776660370; called by muse, mutect2
- HOXD13 | c.543C>A p.N181K | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.29); catalogued as rs13392701; called by muse, mutect2
- KIF2B | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | catalogued as COSV52128836, COSV99276329; called by muse, mutect2
- LAMA3 | c.7955G>T p.G2652V (on ENST00000313654 / NM_198129.4; = p.G1043V on NM_000227.6) | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52529139; called by muse, mutect2
- LRCH2 | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV100406940; called by muse, mutect2, varscan2
- LRP1B | c.9707C>A p.S3236* | Nonsense Mutation (SNP) | VAF 16/283 reads (6%) | catalogued as COSV67185175; called by muse, mutect2
- MAGEC3 | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV68924339; called by muse, mutect2
- MAP7D3 | c.1933C>A p.Q645K | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV60170717; called by muse, mutect2
- MYH1 | c.2609C>T p.T870I | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV56843888; called by muse, mutect2
- MYH13 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1567668771; called by muse, mutect2
- MYO3B | c.3619G>T p.A1207S | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV58693730; called by muse, mutect2
- NID1 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV51625894; called by muse, mutect2, varscan2
- OR10Q1 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV57471529; called by muse, mutect2
- OR14A16 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 17/146 reads (12%) | catalogued as COSV62926832; called by muse, mutect2, varscan2
- OR14K1 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV51721306, COSV99315338; called by muse, varscan2
- OR2L5 | c.716C>A p.T239N | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs760352606; called by muse, mutect2, varscan2
- OR2T33 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100532121; called by muse, mutect2, varscan2
- OR4C6 | c.778del p.V260Wfs*6 | Frame Shift Del (DEL) | VAF 27/272 reads (10%) | catalogued as rs1427758519; called by mutect2, varscan2
- PAQR9 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV61418185; called by muse, mutect2
- PBX2 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as rs757153246, COSV66709526; called by muse, mutect2
- PCDHGA8 | c.1853C>A p.S618* | Nonsense Mutation (SNP) | VAF 20/296 reads (7%) | catalogued as COSV53935874; called by muse, mutect2
- PDE3A | c.980G>T p.W327L | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781120746; called by muse, mutect2
- PDHA2 | c.124T>C p.Y42H | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99756476; called by muse, mutect2
- PLXNA1 | c.4694G>T p.R1565L | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142147514, COSV52530883; called by muse, mutect2
- PNP | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.81); catalogued as COSV64091814; called by muse, mutect2
- PPIAL4G | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 25/492 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.092); catalogued as rs1553321604; called by muse, mutect2
- PRKAA2 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64803603; called by muse, mutect2, varscan2
- RGPD4 | c.2731A>G p.K911E | Missense Mutation (SNP) | VAF 20/381 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.148); catalogued as COSV61746566; called by muse, mutect2
- RGSL1 | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 27/175 reads (15%) | catalogued as rs140214137; called by muse, mutect2, varscan2
- RYR2 | c.7815G>A p.M2605I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as rs1244019330; called by muse, mutect2
- SDS | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1296056926; called by muse, mutect2, varscan2
- SGSM1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV68508538; called by muse, mutect2
- SPTA1 | c.6223C>A p.L2075M | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63757471; called by muse, mutect2, varscan2
- TENM2 | c.6421C>A p.Q2141K (on ENST00000518659 / NM_001122679.2; = p.Q1902K on NM_001080428.3) | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV69135812; called by muse, mutect2
- TRIM11 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52857735; called by muse, mutect2
- TRIM58 | c.1074G>T p.W358C | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825193; called by muse, mutect2, varscan2
- USH2A | c.14216G>T p.R4739I | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as rs12085354; called by muse, mutect2, varscan2
- USH2A | c.799G>T p.V267F | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs1240261228; called by muse, mutect2
- ZNF208 | c.3167C>A p.P1056H | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs1005747789, COSV68108324; called by muse, mutect2
- ABCB7 | c.1705G>A p.G569R (on ENST00000373394 / NM_001271696.3; = p.G570R on NM_004299.6) | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRB2 | c.2963C>A p.S988Y | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ADRB3 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK2 | c.6794C>G p.T2265S | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); called by muse, mutect2
- AP1B1 | c.886C>G p.P296A | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2
- ARPP21 | c.261+1G>T p.X87_splice | Splice Site (SNP) | VAF 12/274 reads (4%) | called by muse, mutect2
- ARSF | c.1671G>T p.Q557H | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2
- ATP1B4 | c.457+1G>T p.X153_splice (on ENST00000218008 / NM_001142447.3; = p.X149_splice on NM_012069.5) | Splice Site (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- ATP4A | c.969C>G p.C323W | Missense Mutation (SNP) | VAF 17/356 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- BACE2 | c.747+2T>C p.X249_splice | Splice Site (SNP) | VAF 17/181 reads (9%) | called by muse, mutect2
- C2orf16 | c.4651C>A p.R1551S | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2
- CADM3 | c.646C>A p.L216I (on ENST00000368125 / NM_001127173.3; = p.L250I on NM_021189.5) | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2
- CES5A | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.123); called by muse, mutect2
- CFAP44 | c.4885G>C p.V1629L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.028); called by muse, mutect2
- COL23A1 | c.635C>A p.P212Q | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.355); called by muse, mutect2
- CSMD3 | c.9035C>A p.T3012N (on ENST00000297405 / NM_001363185.1; = p.T2843N on NM_052900.3) | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYLC1 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); called by muse, mutect2
- DCAF4L2 | c.463T>A p.C155S | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- DENND4B | c.1233C>G p.I411M | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2
- DMD | c.4840G>A p.G1614R | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- DOCK1 | c.1389G>C p.E463D | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- DOCK3 | c.2815G>T p.E939* | Nonsense Mutation (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- FILIP1 | c.3533C>T p.A1178V | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- FMN2 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- FREM3 | c.4066C>T p.Q1356* | Nonsense Mutation (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- GAB4 | c.876G>T p.W292C | Missense Mutation (SNP) | VAF 28/391 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); called by muse, mutect2
- GCSAML | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- GLI3 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 51/487 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GLRA3 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.139); called by muse, mutect2
- GON4L | c.6379G>T p.E2127* | Nonsense Mutation (SNP) | VAF 10/133 reads (8%) | called by muse, mutect2
- GSTK1 | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- GUCY2F | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- HIVEP1 | c.972G>T p.Q324H | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2
- IGKV1D-43 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 18/242 reads (7%) | called by muse, mutect2
- IGKV2-24 | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- ITGB1BP2 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JMJD6 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2
- KIF4B | c.2565G>C p.E855D | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- LAMB2 | c.3001G>T p.D1001Y | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- MPPED2 | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 25/394 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.319); called by muse, mutect2
- MYH10 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- NANOGNB | c.265C>A p.Q89K | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); called by muse, mutect2
- NAV1 | c.3353T>A p.L1118Q | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- NLRP3 | c.2905C>A p.L969M | Missense Mutation (SNP) | VAF 20/355 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NMUR2 | c.126C>A p.S42R | Missense Mutation (SNP) | VAF 48/636 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NOX4 | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2
- NPY1R | c.458G>T p.R153I | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2
- NRCAM | c.2344T>A p.Y782N (on ENST00000379028 / NM_001371124.1; = p.Y766N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NXPH1 | c.6G>T p.Q2H | Missense Mutation (SNP) | VAF 54/493 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OAT | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 46/520 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OMG | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR1J1 | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.111); called by muse, mutect2
- OR2M2 | c.578C>A p.S193* | Nonsense Mutation (SNP) | VAF 19/308 reads (6%) | called by muse, mutect2
- PCCB | c.757A>T p.M253L | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- PCDHB6 | c.124A>C p.T42P | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHGA4 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); called by muse, mutect2
- PDE3B | c.2962C>A p.Q988K | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PEX5 | c.1820T>A p.L607Q (on ENST00000420616; = p.L599Q on NM_000319.5) | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PGK1 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- PGK1 | c.380A>T p.E127V | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- PGM3 | c.422T>C p.I141T | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.122); called by muse, mutect2
- PHF20 | c.1564A>G p.T522A | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLVAP | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); called by muse, mutect2
- PPP1R3F | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- PXDNL | c.2308C>A p.P770T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- QPCT | c.445T>A p.W149R | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.121); called by muse, mutect2
- RAB40A | c.503C>A p.T168K | Missense Mutation (SNP) | VAF 29/459 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.783); called by muse, mutect2
- RAB40A | c.181C>G p.Q61E | Missense Mutation (SNP) | VAF 21/364 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2
- RNASE3 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RNF212B | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2
- RSPO2 | c.713C>G p.T238R | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RTL3 | c.1266G>T p.M422I | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.6882A>T p.E2294D | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SELP | c.2185A>T p.I729F | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2
- SELP | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 16/468 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- SELP | c.1039G>T p.G347C | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC35G3 | c.223T>A p.W75R | Missense Mutation (SNP) | VAF 26/585 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- SLC4A1 | c.1562A>T p.Q521L | Missense Mutation (SNP) | VAF 26/357 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SMAD2 | c.778A>T p.S260C | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.325); called by muse, mutect2
- SPSB4 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SRCIN1 | c.3620C>T p.S1207F (on ENST00000621492; = p.S1173F on NM_025248.3) | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- STX18 | c.761+1G>T p.X254_splice | Splice Site (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- SYT13 | c.923T>A p.L308Q | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- TM9SF4 | c.539A>T p.H180L | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TMEM41B | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); called by muse, mutect2
- TREML2 | c.689C>A p.T230N | Missense Mutation (SNP) | VAF 13/298 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); called by muse, mutect2
- TRIM39 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- UPRT | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); called by muse, mutect2
- USP42 | c.3270G>C p.E1090D | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VCAN | c.8914A>T p.T2972S | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2
- WNT7A | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.361); called by muse, mutect2
- ZFHX4 | c.2047C>A p.H683N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZFPM2 | c.3009C>G p.D1003E | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- ZIC1 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.961); called by muse, mutect2
- ZNF30 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ZNF730 | c.1373G>T p.G458V | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZXDA | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2, varscan2
- ABCA7 | c.768C>T p.S256= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs764988210; called by muse, mutect2, varscan2
- ACHE | c.138C>A p.G46= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV53819799, COSV53822632, COSV99574787; called by muse, mutect2
- ACSM1 | c.1683T>C p.T561= | Silent (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- AFMID | c.459A>T p.P153= | Silent (SNP) | VAF 19/221 reads (9%) | called by muse, mutect2
- AGAP9 | c.921G>C p.L307= | Silent (SNP) | VAF 34/402 reads (8%) | called by muse, mutect2, varscan2
- BAHCC1 | c.7137C>T p.S2379= | Silent (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- BLID | c.138A>T p.P46= | Silent (SNP) | VAF 13/279 reads (5%) | called by muse, mutect2
- CD300LG | c.192C>A p.T64= | Silent (SNP) | VAF 34/444 reads (8%) | called by muse, mutect2
- CDH20 | c.1809C>A p.V603= | Silent (SNP) | VAF 22/394 reads (6%) | called by muse, mutect2
- CFAP65 | c.4473A>T p.I1491= | Silent (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- COL4A6 | c.1329A>G p.P443= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- GLIS3 | c.681G>T p.P227= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- HCFC1 | c.3384C>A p.G1128= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- HSPG2 | c.11656C>T p.L3886= | Silent (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- IGHD4-17 | c.9G>T p.R3= | Silent (SNP) | VAF 16/276 reads (6%) | called by muse, mutect2
- ITPR3 | c.4104G>T p.L1368= | Silent (SNP) | VAF 26/370 reads (7%) | catalogued as COSV100967363; called by muse, mutect2
- LAMA3 | c.7956C>T p.G2652= (on ENST00000313654 / NM_198129.4; = p.G1043= on NM_000227.6) | Silent (SNP) | VAF 31/430 reads (7%) | called by muse, mutect2
- MICALL2 | c.2001G>T p.L667= | Silent (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- MON2 | c.3030G>T p.R1010= | Silent (SNP) | VAF 34/394 reads (9%) | called by muse, mutect2
- MPO | c.1356C>A p.A452= | Silent (SNP) | VAF 23/320 reads (7%) | called by muse, mutect2
- NLRP12 | c.1155C>A p.G385= | Silent (SNP) | VAF 52/642 reads (8%) | called by muse, mutect2
- OR10AG1 | c.810C>A p.T270= | Silent (SNP) | VAF 16/203 reads (8%) | catalogued as rs997537950, COSV56633669; called by muse, mutect2
- OR10Q1 | c.351C>T p.F117= | Silent (SNP) | VAF 10/272 reads (4%) | called by muse, mutect2
- OR51E2 | c.375C>A p.I125= | Silent (SNP) | VAF 19/206 reads (9%) | called by muse, mutect2
- OR5M10 | c.99G>A p.A33= | Silent (SNP) | VAF 40/426 reads (9%) | catalogued as rs781228134, COSV73242255; called by muse, mutect2
- OR5T1 | c.171G>T p.L57= | Silent (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- PDE3A | c.222G>T p.L74= | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- PRR19 | c.579G>T p.R193= | Silent (SNP) | VAF 25/268 reads (9%) | called by muse, mutect2
- RASGEF1C | c.624G>C p.L208= | Silent (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- RBP3 | c.1264C>A p.R422= | Silent (SNP) | VAF 41/552 reads (7%) | called by muse, mutect2
- RNASEL | c.1785G>T p.T595= | Silent (SNP) | VAF 20/358 reads (6%) | catalogued as COSV62376976; called by muse, mutect2
- RNF114 | c.27G>T p.G9= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as rs765946103; called by muse, mutect2, varscan2
- RREB1 | c.4569G>T p.S1523= | Silent (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- RWDD3 | c.261A>G p.L87= | Silent (SNP) | VAF 30/386 reads (8%) | called by muse, mutect2
- SALL3 | c.42G>A p.S14= | Silent (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- SLC30A10 | c.1125C>A p.I375= | Silent (SNP) | VAF 62/411 reads (15%) | called by muse, mutect2, varscan2
- SLITRK2 | c.876T>A p.A292= | Silent (SNP) | VAF 8/163 reads (5%) | called by muse, mutect2
- SLITRK4 | c.1722C>A p.L574= | Silent (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- STARD9 | c.3759G>A p.R1253= | Silent (SNP) | VAF 22/346 reads (6%) | called by muse, mutect2
- TMEM132C | c.408G>T p.L136= | Silent (SNP) | VAF 49/575 reads (9%) | catalogued as COSV70664452; called by muse, mutect2
- TTN | c.54267C>A p.A18089= (on ENST00000591111; = p.A10665= on NM_003319.4) | Silent (SNP) | VAF 34/476 reads (7%) | called by muse, mutect2
- UGT2B17 | c.1443C>T p.A481= | Silent (SNP) | VAF 24/226 reads (11%) | catalogued as rs371257307; called by muse, mutect2
- VSIG4 | c.1110C>A p.I370= | Silent (SNP) | VAF 26/413 reads (6%) | catalogued as COSV66073726; called by muse, mutect2
- ZNF229 | c.982C>A p.R328= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, varscan2
- AC022182.2 | n.119A>G | RNA (SNP) | VAF 11/266 reads (4%) | called by muse, mutect2
- AL109984.1 | n.186+1653G>T | Intron (SNP) | VAF 7/161 reads (4%) | catalogued as COSV63754333; called by muse, mutect2
- ASH1L | chr1:155563294 G>T | 5'Flank (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- ATP2B3 | c.-35C>T | 5'UTR (SNP) | VAF 29/348 reads (8%) | called by muse, mutect2
- COL5A2 | c.*11G>T | 3'UTR (SNP) | VAF 28/484 reads (6%) | called by muse, mutect2
- DCD | c.98-320G>A | Intron (SNP) | VAF 23/172 reads (13%) | called by muse, mutect2, varscan2
- DPYD | c.-6A>T | 5'UTR (SNP) | VAF 32/640 reads (5%) | called by muse, mutect2
- GFRA4 | c.*60T>A | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- GLA | c.-4G>T | 5'UTR (SNP) | VAF 23/517 reads (4%) | called by muse, mutect2
- JAZF1 | c.116-28664G>T | Intron (SNP) | VAF 28/336 reads (8%) | called by muse, mutect2
- LILRA5 | c.-46C>A | 5'UTR (SNP) | VAF 6/131 reads (5%) | called by muse, mutect2
- MARCHF1 | c.-322-85712G>T | Intron (SNP) | VAF 25/400 reads (6%) | called by muse, mutect2
- MASP1 | c.1304-5718A>G | Intron (SNP) | VAF 24/452 reads (5%) | catalogued as COSV99962889; called by muse, mutect2
- PEX10 | c.601-57G>T | Intron (SNP) | VAF 17/261 reads (7%) | called by muse, mutect2
- PNCK | c.539-41G>A | Intron (SNP) | VAF 15/239 reads (6%) | catalogued as rs149305071, COSV100562205; called by muse, mutect2
- PRAMEF20 | c.*5C>A | 3'UTR (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- PSMC1 | c.-41G>T | 5'UTR (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- SLC2A14 | chr12:7895674 C>G | 5'Flank (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2, varscan2
- SLC45A2 | c.-23G>T | 5'UTR (SNP) | VAF 18/462 reads (4%) | called by muse, mutect2
- SRGAP1 | c.1539+533G>T | Intron (SNP) | VAF 26/286 reads (9%) | called by muse, mutect2
- YIPF3 | c.395+329G>T | Intron (SNP) | VAF 23/208 reads (11%) | catalogued as rs1383044718, COSV104411955; called by muse, mutect2, varscan2
- ZNF849P | n.523C>A | RNA (SNP) | VAF 24/340 reads (7%) | called by muse, mutect2
